Somatic mutation profile of tumor specimen 0DH5VO from CCDI case PBBPKG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,337 days).
Specimen 0DH5VO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaaffc2a-83e3-44a5-8206-eaedaa2e6b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5UE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a0cce5f-d8ba-41c4-be3a-81ab5949e5d1

The open-access MAF lists 38 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 8, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP250 | c.5452G>A p.E1818K | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.217); catalogued as COSV61173925; called by muse, mutect2
- OR4K15 | c.515C>T p.S172L (on ENST00000305051; = p.S148L on NM_001005486.1) | Missense Mutation (SNP) | VAF 87/774 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59300549, COSV59300912; called by muse, mutect2, varscan2
- C5orf15 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A4 | c.3377C>G p.S1126C | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CPLANE2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 90/632 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPG5 | c.4760G>C p.R1587T | Missense Mutation (SNP) | VAF 103/851 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FOXO6 | c.335C>G p.S112W | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GANAB | c.1011G>C p.K337N | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GLCE | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 129/880 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- HYDIN | c.13431C>G p.I4477M | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- KCNH4 | c.1434C>G p.I478M | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- LMTK3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MINDY2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 61/485 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MRC2 | c.4422G>A p.M1474I | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.214); called by muse, mutect2
- PCDH8 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PLEKHG2 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SLC25A23 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- XBP1 | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 144/1036 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHST7 | c.918G>A p.Q306= | Silent (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- CYP4B1 | c.21C>A p.S7= | Silent (SNP) | VAF 69/408 reads (17%) | catalogued as rs745774872; called by muse, mutect2, varscan2
- ERP29 | c.741C>T p.I247= | Silent (SNP) | VAF 70/435 reads (16%) | catalogued as rs1182490538; called by muse, mutect2, varscan2
- EVI2B | c.1032T>A p.L344= | Silent (SNP) | VAF 189/936 reads (20%) | called by muse, mutect2, varscan2
- GTF2F1 | c.147G>A p.R49= | Silent (SNP) | VAF 45/401 reads (11%) | called by muse, mutect2, varscan2
- HMCN2 | c.13242C>G p.L4414= | Silent (SNP) | VAF 45/342 reads (13%) | called by muse, mutect2, varscan2
- MAOB | c.1560C>T p.V520= | Silent (SNP) | VAF 78/556 reads (14%) | called by muse, mutect2, varscan2
- PPFIA3 | c.3501C>T p.L1167= | Silent (SNP) | VAF 40/258 reads (16%) | called by muse, mutect2, varscan2
- SMC2 | c.3333C>T p.I1111= | Silent (SNP) | VAF 123/885 reads (14%) | called by muse, mutect2, varscan2
- GTF2F1 | c.133-62G>A | Intron (SNP) | VAF 16/68 reads (24%) | catalogued as rs779212029; called by muse, mutect2
- HSD17B11 | c.*15G>A | 3'UTR (SNP) | VAF 70/590 reads (12%) | catalogued as COSV100839596, COSV64154750; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- MYO1F | c.2621+79G>A | Intron (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- PDLIM7 | c.-11-69G>C | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- PPOX | c.988-97G>A | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2
- SLC7A3 | c.*7C>T | 3'UTR (SNP) | VAF 119/732 reads (16%) | catalogued as COSV99979313, COSV99979901; called by muse, mutect2, varscan2
- TBC1D29P | n.2811G>A | RNA (SNP) | VAF 57/489 reads (12%) | called by muse, varscan2
- TTC9B | c.611-43G>A | Intron (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.10360+5517G>A | Intron (SNP) | VAF 132/847 reads (16%) | catalogued as rs1457610610, COSV100601297; called by muse, mutect2, varscan2
- USP36 | c.758-14C>G | Intron (SNP) | VAF 32/246 reads (13%) | catalogued as rs192823009; called by muse, mutect2
